Gene-level copy-number profile of tumor specimen ALCH-AEPK-TTP1-A from ALCHEMIST case ALCH-AEPK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.6 years (25,431 days).
Specimen ALCH-AEPK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4313ee34-923a-46a6-a9a2-0fde41a740db.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEPK-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/b86d8509-80af-4458-a860-0c16525db0bb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 87; copy number 1: 2,170; copy number 2: 55,248; copy number 3: 639; copy number 4: 120; copy number 5: 45; copy number 6: 84; copy number 7: 5; copy number 12: 3.

Homozygous deletions (total copy number 0; autosomes only): 82 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:232,343,116–232,382,889, 5 genes (within-gene range 0–2): NRBF2P6, ECEL1P3, AC068134.3, ALPP, AC068134.1.
- chr2:232,479,827–232,487,834, 1 gene: ECEL1.
- chr2:241,809,065–241,817,413, 1 gene (within-gene range 0–2): NEU4.
- chr4:9,567,474–9,691,786, 1 gene (within-gene range 0–2): AC105916.1.
- chr4:9,677,308–9,742,361, 5 genes: ENPP7P11, FAM86MP, ALG1L3P, Metazoa_SRP, AC098976.1.
- chr5:470,456–524,449, 1 gene (within-gene range 0–2): SLC9A3.
- chr5:524,109–535,882, 2 genes: AC106772.2, MIR4456.
- chr5:177,494,995–177,516,961, 3 genes (within-gene range 0–2): AC145098.1, DOK3, DDX41.
- chr7:76,470,162–76,478,856, 2 genes (within-gene range 0–1): FDPSP2, AC005522.1.
- chr7:152,435,695–152,465,549, 3 genes (within-gene range 0–2): FABP5P3, CCT8L1P, LINC01003.
- chr7:156,944,721–156,945,645, 1 gene: AC006357.1.
- chr14:63,543,569–63,568,308, 2 genes: AL136038.3, AL136038.1.
- chr15:25,169,337–25,250,940, 45 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr16:58,665,109–58,706,297, 2 genes: SLC38A7, AC012183.1.
- chr20:63,956,704–64,049,639, 5 genes (within-gene range 0–2): ZNF512B, SAMD10, PRPF6, C20orf204, SOX18.
- chr20:64,073,181–64,079,988, 2 genes: RGS19, MIR6813.
- chr20:64,083,380–64,084,359, 1 gene (within-gene range 0–1): LKAAEAR1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 137 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:136,791,344–136,810,042, 4 genes, copy number 6–12 (within-gene range 2–12): TMEM141, AL355987.3, CCDC183, AL355987.4.
- chr9:136,803,927–136,808,848, 1 gene, copy number 12 (within-gene range 2–12): CCDC183-AS1.
- chr12:57,452,323–57,846,729, 40 genes, copy number 5: INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2.
- chr12:62,935,701–62,935,802, 1 gene, copy number 5: Y_RNA.
- chr12:65,169,583–67,069,162, 33 genes, copy number 6–7 (within-gene range 4–7): LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB, GRIP1, OSBPL9P5, OSBPL9P4.
- chr12:67,265,842–68,971,570, 46 genes, copy number 6: GGTA2P, CAND1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr12:73,115,957–73,846,188, 7 genes, copy number 6: AC090503.2, LINC02444, AC090503.1, AC087879.1, RNU6-1012P, LINC02445, U8.
- chr16:87,945,058–87,945,202, 1 gene, copy number 5: AC127455.1.
- chr20:62,872,250–62,948,475, 4 genes, copy number 5–6: ARF4P2, DIDO1, AL117379.1, GID8.

Autosomal genes at a single copy (total copy number 1): 2,155. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
